Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94K, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94K-01A (Primary Tumor).

ICD-0-3

ICD-0-3

Mixed germ cell tumor
9085/3
Site @ Testis NOS C62.9
9/13/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

Product of left radical orchiectomy:

- Mixed germ cell malignant tumor, composed of:
- . Embryonal carcinoma: 80%
- . Immature grade I teratoma: 20%
- . Neoplasia size: 5.0 x 4.0 x 4.0 cm.
- Remnant testicular parenchyma exhibiting germ cell intratubular neoplasia
- Spermatic cord, tunica albuginea and tunica vaginalis free of neoplasia
- Angiolymphatic infiltration not observed.
- Epididymis without particularities
- Resection margin free of neoplasia.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Topic testis	Mixed germ cell tumor non-seminomatous	pT1

Criteria	W 11/18/13	Yes	No

Source: NCI Genomic Data Commons file 432ff7e4-928d-4598-82ad-e0dda8bcf4f9 (TCGA-YU-A94K-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).